FM case AD3754 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/5c11423d-b53b-487b-86d1-78aa6e921ef0

Male, 70.6 years: Carcinoma, NOS (ICD-O-3 8010/3) of the pancreas; metastasis biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
